Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81G-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: left adrenal

This is a 5x4.1x4 cm measuring tan tumor surrounded by a thin layer of normal adrenal tissue.

Histologically, the tumor is composed of zellballen surrounded by thin layers of connective tissue. Tumor cells are partly strongly enlarged, however, no mitosis or necrosis are visible. Several focal destructions of the capsula can be noted with invasion of the tumor into the adjacent adipose tissue.

Immunohistochemically, the tumor strongly stains positive for synaptophysin and chromogranin. Single sustentacular cells are identified by positive staining for S100. Only the adjacent adrenal parenchyma stains positive for MART1. Tumor weakly stains positive, but the normal adrenal tissue strongly stains positive for inhibin. With Ki67, a proliferation index of <1% is found.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site @ Adrenal gland NOS C74.9
9/10/17/13

Source: NCI Genomic Data Commons file 28ab4319-fb22-47cc-9085-2cf1f7399fd6 (TCGA-WB-A81G.90ACEC05-1D9B-4A6E-A1D6-B9F09159A7C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).